Somatic mutation profile of tumor specimen TCGA-16-0846-01A (aliquot TCGA-16-0846-01A-01W-0424-08) from TCGA case TCGA-16-0846, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 85.2 years (31,111 days).
Specimen TCGA-16-0846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ab5e5e3-0bb8-4ad0-b050-82794af054aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0846-10A (Blood Derived Normal), aliquot TCGA-16-0846-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e4beea-4851-43dd-bbba-58139b6bc034

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Frame Shift Ins 28, Silent 17, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 40/310 reads (13%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 36/220 reads (16%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 58/433 reads (13%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TBX5 | c.1158dup p.S387Qfs*100 | Frame Shift Ins (INS) | VAF 14/144 reads (10%) | catalogued as rs1064795870; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 147/234 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI3 | c.360dup p.G121Rfs*167 | Frame Shift Ins (INS) | VAF 9/63 reads (14%) | catalogued as rs745481319; called by mutect2, pindel
- BIN2 | c.217+1G>A p.X73_splice | Splice Site (SNP) | VAF 41/141 reads (29%) | catalogued as COSV57204516; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | catalogued as rs372345940; called by mutect2, varscan2
- C9 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV54675347; called by muse, mutect2, varscan2
- CARD11 | c.1663dup p.R555Pfs*38 | Frame Shift Ins (INS) | VAF 17/132 reads (13%) | catalogued as rs762770988; called by mutect2, varscan2
- CD38 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56889076; called by muse, mutect2
- CNDP1 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100722549, COSV62595393; called by muse, mutect2
- COL3A1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.328); catalogued as rs187907868, COSV58584690, COSV58597018; called by muse, mutect2, varscan2
- CPA4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs751553332, COSV55982374, COSV55982540; called by muse, mutect2, varscan2
- DMD | c.4170C>G p.D1390E | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs886043687, COSV63742989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMSY | c.1655dup p.K553Qfs*4 | Frame Shift Ins (INS) | VAF 9/94 reads (10%) | catalogued as rs1436291685; called by mutect2, pindel
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 29/258 reads (11%) | catalogued as rs756407271; called by mutect2, varscan2
- FAM124A | c.202G>A p.V68I (on ENST00000322475 / NM_001242312.2; = p.V104I on NM_145019.4) | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs1433534038, COSV54475053; called by mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | catalogued as rs755836480; called by mutect2, varscan2
- FOXA1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV51644795; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 24/153 reads (16%) | catalogued as rs752538869; called by mutect2, varscan2
- GIMAP7 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs748612836, COSV57958762; called by muse, mutect2, varscan2
- HOXD4 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60459549; called by muse, mutect2, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 70/590 reads (12%) | catalogued as rs745545309; called by mutect2, varscan2
- IL4R | c.500A>T p.N167I | Missense Mutation (SNP) | VAF 191/480 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV50139988; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs780982673; called by mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | catalogued as rs750932259; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 54/230 reads (23%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC30 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV67301504; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 14/73 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MFSD2A | c.895C>T p.R299W (on ENST00000372809 / NM_001136493.3; = p.R286W on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs373419262; called by muse, mutect2, varscan2
- MUC17 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs777479634, COSV60283635; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 14/108 reads (13%) | catalogued as rs761123152; called by mutect2, varscan2
- NAV2 | c.2174A>G p.H725R (on ENST00000396087 / NM_001244963.2; = p.H702R on NM_145117.5) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as rs768598584, COSV62318643; called by muse, mutect2, varscan2
- NLRX1 | c.2663dup p.A889Cfs*3 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs751657075; called by pindel, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 24/124 reads (19%) | catalogued as rs754860965; called by mutect2, varscan2
- OLFML2B | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54195095; called by muse, mutect2, varscan2
- OR10H5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58277714; called by muse, mutect2, varscan2
- OR51A4 | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV66749216; called by muse, mutect2, varscan2
- OR6C75 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58551679; called by muse, mutect2, varscan2
- OVGP1 | c.1054dup p.A352Gfs*10 | Frame Shift Ins (INS) | VAF 38/327 reads (12%) | catalogued as rs763064364; called by mutect2, varscan2
- PCDH11X | c.2287T>A p.F763I | Missense Mutation (SNP) | VAF 143/236 reads (61%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.698); catalogued as COSV53452590; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 122/972 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 48/298 reads (16%) | catalogued as rs778683789; called by mutect2, varscan2
- PRKDC | c.6124C>T p.Q2042* | Nonsense Mutation (SNP) | VAF 41/221 reads (19%) | catalogued as COSV58047529, COSV58067452; called by muse, mutect2, varscan2
- PTEN | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 92/133 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64293021, COSV64299567; called by muse, mutect2, varscan2
- PUS7 | c.1363T>G p.Y455D | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.659); catalogued as COSV62676270; called by muse, mutect2, varscan2
- RP1 | c.4490A>T p.E1497V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV55113053; called by muse, mutect2, varscan2
- SCN9A | c.4903T>A p.F1635I (on ENST00000303354; = p.F1624I on NM_002977.3) | Missense Mutation (SNP) | VAF 207/430 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57604428, COSV57620670; called by muse, mutect2, varscan2
- SEC23IP | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV64831075; called by muse, mutect2, varscan2
- SEL1L2 | c.1842G>T p.L614F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as COSV53149709; called by muse, mutect2, varscan2
- SERPING1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as rs867177349, COSV99557995; called by muse, mutect2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs777796332; called by mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 50/321 reads (16%) | catalogued as rs746556543; called by mutect2, varscan2
- SHC1 | c.92dup p.E32Gfs*23 | Frame Shift Ins (INS) | VAF 15/120 reads (13%) | catalogued as rs752843778; called by mutect2, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as rs748701652; called by mutect2, varscan2
- SMC1B | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV62528915; called by muse, mutect2, varscan2
- TBX5 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 195/459 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59859397; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 44/246 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TRIM51 | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV55265016; called by muse, mutect2, varscan2
- TRPA1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV51557794; called by muse, mutect2, varscan2
- TSHZ3 | c.1014_1015insA p.G339Rfs*26 | Frame Shift Ins (INS) | VAF 48/456 reads (11%) | catalogued as COSV99551716; called by mutect2, varscan2
- VDAC2 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV53685458; called by muse, mutect2, varscan2
- YY1AP1 | c.1868T>A p.V623D (on ENST00000295566 / NM_139118.2; = p.V566D on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs760889972, COSV55119929; called by muse, mutect2, varscan2
- ZBP1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV59060911; called by muse, mutect2, varscan2
- ZNF680 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV59014571; called by muse, mutect2, varscan2
- ZNF776 | c.1273G>T p.V425F | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57814800; called by muse, mutect2
- ZFP28 | c.780del p.N260Kfs*17 | Frame Shift Del (DEL) | VAF 105/357 reads (29%) | called by mutect2, pindel, varscan2
- C1QTNF6 | c.759C>T p.R253= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs778601751, COSV55396006; called by muse, mutect2, varscan2
- CPVL | c.102A>G p.P34= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV55300603; called by muse, mutect2, varscan2
- FAM151A | c.591C>A p.V197= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV56363422, COSV56366793; called by muse, mutect2, varscan2
- FGD6 | c.879A>G p.S293= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs1317708670, COSV59691547; called by muse, mutect2, varscan2
- GABRE | c.975C>A p.T325= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs483352728, COSV64819196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT7 | c.1026C>T p.P342= | Silent (SNP) | VAF 138/240 reads (58%) | catalogued as COSV53928056; called by muse, mutect2, varscan2
- HYDIN | c.9939C>T p.A3313= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs553587582, COSV66863115; called by muse, mutect2, varscan2
- ILF3 | c.1701A>G p.Q567= | Silent (SNP) | VAF 114/279 reads (41%) | catalogued as COSV51555305; called by muse, mutect2, varscan2
- KIAA0319 | c.2550G>A p.S850= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs890623665, COSV65497245; called by muse, mutect2, varscan2
- LAMB3 | c.2058C>T p.D686= | Silent (SNP) | VAF 28/447 reads (6%) | catalogued as COSV61915891; called by muse, mutect2
- MYOCD | c.1458G>A p.P486= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs781734613, COSV58500177; called by muse, mutect2, varscan2
- NCBP1 | c.2340C>T p.A780= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV64304939; called by muse, mutect2, varscan2
- PGLYRP1 | c.576C>T p.H192= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- PRKAG3 | c.1263G>A p.L421= | Silent (SNP) | VAF 345/668 reads (52%) | catalogued as COSV52101267; called by muse, mutect2, varscan2
- RELN | c.10101C>T p.N3367= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as rs757164573, COSV58992591; ClinVar: likely benign; called by muse, mutect2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 104/676 reads (15%) | catalogued as rs140753733; called by muse, mutect2
- Z83844.2 | c.1188G>A p.A396= | Silent (SNP) | VAF 134/304 reads (44%) | catalogued as rs746933688, COSV60927392; called by muse, mutect2, varscan2
- MIR498 | n.49C>T | RNA (SNP) | VAF 64/146 reads (44%) | catalogued as rs750516141; called by muse, mutect2, varscan2
- POLR3G | c.*120G>A | 3'UTR (SNP) | VAF 52/183 reads (28%) | catalogued as rs375576885; called by muse, mutect2, varscan2
- TM9SF1 | c.1427+39C>G | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as COSV55779058, COSV55779630, COSV99938056; called by muse, mutect2, varscan2
